Surgical pathology report (de-identified scan), TCGA case TCGA-FW-A3I3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site International Genomics Consortium, specimen TCGA-FW-A3I3-06A (Metastatic).

[page 1 of 3]
Sex: Female
D.O.B.:

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Total pelvic exenteration:

Tumor Characteristics:

1. Histologic type: Malignant melanoma.
2. Tumor site: Vaginal wall.
3. Tumor size: Tumor is multifocal with the largest confluent areas measuring 1.1 x 1.0 x 0.5 cm and 2.0 x 1.7 x 1.3, respectively.

Surgical Margin Status:

1. Largest area of tumor is located in the deep soft tissue of the vagina, approximately 0.1 cm from the inked deep margin. There is no definitive connection to surface epithelium. This lesion extends to a depth of at least 1.7 cm from the overlying surface although there is no distinct connection with the overlying epithelium. One focus of tumor extends to involve the underlying urethra. All other mucosal margins are negative for tumor. The associated bladder and colon are uninvolved by tumor.

Other:

1. Other significant findings:

Uterus:

Cervix without significant abnormality.
Endometrium with weakly proliferative architecture.
No diagnostic evidence of atypical hyperplasia or malignancy.

Myometrium:

Leiomyomata.

Serosa:

No significant abnormality.

Bilateral ovaries with endometriosis.

Foci of endometriosis of soft tissue causing adherence of lateral wall of cervix to left ovary.

Bilateral fallopian tubes without significant abnormality.

Four associated lymph nodes, negative for metastatic disease.

2. pTNM stage: pT4b N0.

B. Left pelvic lymph nodes, excision:

Eight lymph nodes, negative for metastatic disease.

C. Right pelvic lymph nodes, excision:

Seven lymph nodes, negative for metastatic disease.

D. Abdominal wall, biopsy:

Negative for malignancy.

Electronic Signature:

COMMENTS:

Appropriately controlled immunohistochemical stain performed on block A10 show the following results:

Melan-A: Positive in majority of lesional cells.

Findings consistent with melanoma.

CLINICAL INFORMATION

ICD-0-3
Melanoma, NOS 8720/3
Path: Site: Skin, NOS C44.9
CQCF vagina, NOS C52.9

hw 12/2/11

[page 2 of 3]
CLINICAL HISTORY:

Preoperative Diagnosis: Vaginal melanoma.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Total pelvic exenteration, suture at one of the lesions

B. Left pelvic lymph node

C. Right pelvic lymph node

D. Abdominal wall

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in four containers labeled with the patient's name

A. Container A is additionally labeled 'total pelvic exenteration' and contains a total pelvic exenteration specimen having overall dimensions of 26.0 x 13.5 x 12.5 cm. This composite specimen is comprised of perineal skin (13.0 x 6.8 cm), vagina (10.0 cm in length x 3.5 cm in diameter), urethra (7.5 cm in length x 0.5 cm in diameter), bladder (6.5 x 6.0 x 4.0 cm), right ureter (7.5 cm in length x 0.4 cm in diameter), left ureter (6.5 cm in length x 0.5 cm in diameter), uterine cervix (5.0 cm in length x 4.5 x 4.5 cm in diameter), uterine corpus (6.5 cm in length x 5.5 x 4.0 cm), right fimbriated fallopian tube (6.3 cm in length and ranging from 0.4 to 0.7 cm in diameter), right ovary (3.5 x 2.0 x 1.7 cm), left fallopian tube (3.5 cm in length and ranging from 0.5 to 0.7 cm in diameter), left ovary (4.0 x 2.8 x 1.8 cm), rectosigmoid colon (19.0 cm in length and ranging from 3.5 up to 4.5 cm in diameter), and abundant yellow-tan fibroadipose tissue partially surfaced by purple-gray glistening fibromembranous soft tissue at the bladder dome. The peritoneal skin features clitoris, vaginal and anal orifices. No skin lesions are identified. Within the vagina and involving the vaginal mucosa are multiple pink-tan polypoid lesions. One bears a suture. The sutured lesion is 1.1 x 1.0 x 0.5 cm and the remaining lesion is 6.0 x 4.0 x 1.5 cm. These lesions approach to within 3.5 cm of the closest perineal skin edge, and 2.5 cm of the cervix. On section, the sutured lesion approaches to within 4.0 cm of the clitoris and does not involve it. The sutured lesion is present at the urethral orifice and focally extends to involve the urethral mucosa. The remainder of the urethra is lined by pink-tan, glistening and focally erythematous mucosa with no additional lesions. Sections through these lesions reveal a 2.0 x 1.7 x 1.3 cm well-circumscribed nodule bearing a pink-tan hemorrhagic, centrally necrotic cut surface that resides 0.7 cm below the anterior vaginal mucosa and approaches to within less than 0.1 cm of the deep inked soft tissue margin. Additionally, this nodule approaches to within 0.7 cm of the bladder wall.

The ectocervical mucosa is pink-tan and glistening and features a central 1.0 cm patent os. The endocervical canal is yellow-tan, fibrous and indurated. The left ovary is adherent to the left lateral wall of the cervix. It is dense and fibrotic; however, no discrete masses are identified. The endometrium is pink-tan and glistening with an average thickness of 0.3 cm. The surrounding myometrium is pink-tan and fibrous with an average thickness of 2.1 cm. Within the myometrium are two well-circumscribed nodules, 0.4 and 1.0 cm in greatest dimension. These nodules feature gray-white whorled cut surfaces with no evidence of hemorrhage or necrosis.

The right ovary is pink-tan and lobulated and is sectioned to reveal a pink-tan fibrous cut surface with gray-white corpus albicans and a 1.5 cm uniloculated subcortical cyst. The cyst features a smooth inner lining and contains clear, watery fluid. The aforementioned left ovary is pink-tan and lobulated. Sections through the ovary reveal a cystic and solid cut surface. The cysts contain yellow-tan serous fluid and feature gray-white papillary excrescences up to 0.6 cm in greatest dimension. The solid areas are comprised of pink-tan fibrous stroma.

The anterior bladder wall features a 2.0 x 1.5 cm defect featuring smooth, regular borders consistent with cut surface. The edge of the defect is inked blue. The bladder mucosa is pink-tan and glistening with the normal folds. No discrete masses are identified.

The rectosigmoid colon is opened to reveal a wall averaging 1.0 cm in thickness. The mucosa is pink-tan and glistening with the normal folds. Multiple diverticuli are identified, but no masses or perforations are seen.

On section and palpation, six firm fatty possible lymph nodes are identified within the associated soft tissues. These range from 0.2 up to 0.5 cm in greatest dimension. Representative sections are submitted in cassettes A1 through 36 labeled as follows: 1 - right ureter margin, en face; 2 - left ureter margin, en face; 3 - right skin edge, perpendicular; 4 - left skin edge, perpendicular; 5 - anterior skin edge, perpendicular; 6 - posterior skin edge, perpendicular; 7 - clitoris; 8 - first sutured mass at urethral orifice to include urethral mucosa; 9 - anterior subvaginal mucosal lesion to include vaginal mucosa inked soft tissue margin and bladder wall; 10 through 12 - remainder of anterior subvaginal mucosal lesion to include inked deep margin; 13 through 15 - posterior vaginal mucosal lesion to include inked soft tissue margin in cassette 13; 16 - anterior endoectocervix; 17 - posterior endoectocervix; 18 - left lateral wall of cervix to adherent left ovary; 19 and 20 - full thickness anterior endomyometrium; 21 - posterior endomyometrium; 22 - whorled nodules; 23 - right ureteral orifice; 24 - left ureteral orifice; 25 - anterior bladder defect to include normal appearing bladder mucosa; 26 - proximal colonic margin, en face; 27 and 28 - full thickness sections to include diverticula; 29 - right tube and ovary; 30 - left tube; 31 through 35 - entire left ovary; 36 - six whole possible lymph nodes. Additionally a yellow, blue, and green cassette are submitted for genomics research, each labeled

B. Container B is additionally labeled 'left pelvic lymph nodes' and contains a 6.8 x 6.0 x 4.0 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, eight firm fatty possible lymph nodes are identified ranging from 0.5 up to 4.0 cm in greatest dimension. They are entirely submitted in cassettes B1 through 10 labeled as follows: B1 - three whole possible lymph nodes; B2 through 4 - one whole possible bisected lymph node in each cassette; B5 through 7 - one whole possible lymph node, quadrisectioned; B8 through 10 - one whole possible lymph node, quadrisectioned.

[page 3 of 3]
C. Container C is additionally labeled 'right pelvic lymph node' and contains a 5.7 x 5.4 x 3.0 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, seven firm fatty possible lymph nodes are identified ranging from 0.8 up to 5.0 cm in greatest dimension. They are entirely submitted in cassettes C1 through 9 labeled as follows: C1 - four whole possible lymph nodes; C2 and 3 - one whole possible lymph node, trisected; C4 and 5 - one whole possible lymph node, trisected; C6 through 9 - one whole possible lymph node, serially sectioned.

D. Container D is additionally labeled 'abdominal wall' and contains a 7.0 x 5.7 x 1.5 cm yellow-tan fibrofatty soft tissue partially surfaced by purple-gray fibromembranous soft tissue. Sectioning reveals a yellow-tan homogeneous, fibrofatty cut surface. No nodules or lesions are identified. Representative sections are submitted in cassettes D1 through 4 labeled

Source: NCI Genomic Data Commons file 9832469b-60e5-43c8-bbd5-aa11dac1659e (TCGA-FW-A3I3.6B26B4FD-8A1B-4869-AC81-8465323C56FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).